Somatic mutation profile of tumor specimen BA2106D (aliquot aq-BA2106D) from BEATAML1.0 case 2055, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 35.8 years (13,074 days).
Specimen BA2106D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa5b14d5-8da7-4de4-aede-39a13bec38c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2465D (Solid Tissue Normal), aliquot aq-BA2465D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa972e1e-af5d-400b-8c66-05ad68615677

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 94/188 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 79/174 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 34/89 reads (38%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GLP1R | c.283+1G>A p.X95_splice | Splice Site (SNP) | VAF 31/58 reads (53%) | catalogued as rs1274581458; called by muse, mutect2, varscan2
- HSD17B2 | c.834G>C p.K278N | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs201533843; called by muse, varscan2
- KCNH5 | c.344G>T p.R115I | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100525334; called by muse, mutect2, varscan2
- PPFIA3 | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1251387072; called by muse, mutect2, varscan2
- RAD21 | c.972_973insT p.I325Yfs*3 | Frame Shift Ins (INS) | VAF 58/194 reads (30%) | catalogued as COSV52057557; called by mutect2, pindel*, varscan2
- SLU7 | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs200524740; called by muse, varscan2
- TRIM48 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 144/311 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs769250158, COSV70161369; called by muse, mutect2, varscan2
- AC069544.2 | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- KCNMB3 | c.186del p.F63Lfs*3 | Frame Shift Del (DEL) | VAF 81/210 reads (39%) | called by mutect2, pindel, varscan2
- PRR36 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2, varscan2
- LUZP1 | c.2244G>A p.E748= | Silent (SNP) | VAF 53/117 reads (45%) | called by muse, mutect2, varscan2
- PPP2R5B | c.384C>T p.D128= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs1565100254; called by muse, mutect2, varscan2
- DAO | chr12:108876879 A>G | 5'Flank (SNP) | VAF 99/202 reads (49%) | called by muse, mutect2, varscan2
- MLIP | c.613-11253C>A | Intron (SNP) | VAF 107/233 reads (46%) | called by muse, mutect2, varscan2
